Somatic mutation profile of tumor specimen C3L-01032-01 (aliquot CPT0170510019) from CPTAC case C3L-01032, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.8 years (19,276 days).
Specimen C3L-01032-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4242feb5-687f-4508-a75e-ec1ccd8eff77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01032-31 (Blood Derived Normal), aliquot CPT0167270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac41ae60-d14c-49d8-b1d8-9681b867272c

The open-access MAF lists 103 somatic variants for this specimen: 77 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 19, Frame Shift Del 4, Splice Site 4, Intron 3, Splice Region 2, In Frame Del 2, RNA 2, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.4894_4895del p.S1632Yfs*6 | Frame Shift Del (DEL) | VAF 71/201 reads (35%) | catalogued as rs397507748; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 275/568 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 695/1518 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALS2CL | c.2736del p.N913Tfs*26 | Frame Shift Del (DEL) | VAF 100/701 reads (14%) | catalogued as COSV59671270; called by pindel, varscan2
- ARHGEF26 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV62852843; called by muse, mutect2, varscan2
- CCDC144A | c.1928G>C p.C643S | Missense Mutation (SNP) | VAF 98/353 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100138553; called by muse, mutect2, varscan2
- CNBD1 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1483342968, COSV101575261; called by muse, mutect2
- CUX2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 422/714 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376298955; called by muse, mutect2, varscan2
- EPB41L1 | c.955T>A p.F319I | Missense Mutation (SNP) | VAF 64/1482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151360; called by muse, mutect2
- GLI4 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 515/1826 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100391048; called by muse, mutect2, varscan2
- GPR17 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 168/681 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs755635107, COSV55756400; called by muse, mutect2, varscan2
- IGDCC3 | c.1453G>C p.V485L | Missense Mutation (SNP) | VAF 313/889 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs552951892; called by muse, mutect2, varscan2
- LCN8 | c.517-5C>T | Splice Region (SNP) | VAF 175/518 reads (34%) | catalogued as rs1042605820; called by muse, mutect2, varscan2
- LMBR1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs200345135, COSV62218025; called by muse, mutect2, varscan2
- NF2 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 271/655 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100098489; called by muse, mutect2, varscan2
- OFD1 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs752818939; called by muse, mutect2, varscan2
- PCDH15 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 241/1146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs573043647, COSV57311329, COSV57330716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB7 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as rs1372083895; called by muse, mutect2, varscan2
- PLEKHM1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 329/997 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs763911008, COSV101378669; called by muse, mutect2, varscan2
- RGS1 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 65/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66506294; called by muse, mutect2, varscan2
- SEC61A2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 91/847 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100036454; called by muse, mutect2, varscan2
- WDFY4 | c.5804G>A p.G1935D | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1189664648; called by muse, mutect2, varscan2
- ZBTB11 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57244586; called by muse, mutect2, varscan2
- ZNF518A | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs782439291; called by muse, mutect2, varscan2
- ABCC1 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 158/633 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ABCC3 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 112/904 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACAN | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 133/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTL7B | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 117/563 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ADAM10 | c.736-1G>C p.X246_splice | Splice Site (SNP) | VAF 61/492 reads (12%) | called by muse, mutect2, varscan2
- ADGRL3 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 245/1122 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANGPTL6 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ARSL | c.1745G>A p.C582Y | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C3orf38 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 155/691 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CDCA2 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 83/470 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DGAT2L6 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.056); called by muse, varscan2
- FAM25G | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 54/1188 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- FAM71E2 | c.2010G>C p.K670N | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- FOXP3 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GGT1 | c.1450-2del p.X484_splice | Splice Site (DEL) | VAF 153/1408 reads (11%) | called by mutect2, pindel, varscan2
- GUSBP10 | n.370G>T | Splice Region (SNP) | VAF 52/298 reads (17%) | called by muse, mutect2, varscan2
- HSD11B1L | c.61A>G p.N21D | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGSF9B | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 83/375 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- IL10RA | c.1471G>C p.A491P | Missense Mutation (SNP) | VAF 58/873 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- INSYN2B | c.713_719del p.D238Vfs*8 | Frame Shift Del (DEL) | VAF 50/264 reads (19%) | called by mutect2, pindel, varscan2
- ITM2C | c.12del p.S5Afs*32 | Frame Shift Del (DEL) | VAF 71/280 reads (25%) | called by mutect2, pindel, varscan2
- LRRTM4 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- MUC16 | c.7192G>C p.G2398R | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO15A | c.2169G>T p.E723D | Missense Mutation (SNP) | VAF 235/528 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NF2 | c.835A>T p.K279* | Nonsense Mutation (SNP) | VAF 265/643 reads (41%) | called by muse, mutect2, varscan2
- NR0B1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 380/1742 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NTHL1 | c.530_544del p.Y177_F181del (on ENST00000219066; = p.Y169_F173del on NM_002528.7 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 95/969 reads (10%) | called by mutect2, pindel
- PCDHB6 | c.1432T>C p.S478P | Missense Mutation (SNP) | VAF 167/2808 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- PCSK9 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 25/926 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- PCYT2 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 28/946 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PIH1D1 | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 163/602 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PIK3CB | c.2887G>C p.D963H | Missense Mutation (SNP) | VAF 21/482 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- PLEKHG4 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 50/1692 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- POU2F2 | c.129+2T>G p.X43_splice | Splice Site (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2, varscan2
- PRR33 | c.926_937del p.V309_P312del | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- RABL6 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 23/610 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM20 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2
- RNASE13 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 111/436 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPL3 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 291/659 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- RYR3 | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 33/349 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2
- SON | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 272/1375 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- SOST | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 365/918 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- SRPK3 | c.1147+1G>T p.X383_splice | Splice Site (SNP) | VAF 90/312 reads (29%) | called by muse, mutect2, varscan2
- TCEAL4 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TET3 | c.3034_3035insC p.K1012Tfs*41 | Frame Shift Ins (INS) | VAF 127/444 reads (29%) | called by mutect2, pindel, varscan2
- THOC7 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TIAM1 | c.4706C>G p.A1569G | Missense Mutation (SNP) | VAF 95/359 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNK2 | c.3044T>C p.M1015T | Missense Mutation (SNP) | VAF 55/1184 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- TOPAZ1 | c.3125G>C p.R1042P | Missense Mutation (SNP) | VAF 117/391 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC2 | c.1282T>A p.S428T | Missense Mutation (SNP) | VAF 219/946 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC13C | c.4208A>C p.Q1403P | Missense Mutation (SNP) | VAF 169/431 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UQCRC2 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.142); called by muse, mutect2
- ZNF208 | c.2808G>T p.K936N | Missense Mutation (SNP) | VAF 119/555 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AFF3 | c.1833G>A p.A611= | Silent (SNP) | VAF 37/476 reads (8%) | called by muse, mutect2
- FABP1 | c.75G>A p.P25= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs145520267; called by muse, mutect2
- FAM47B | c.690T>A p.T230= | Silent (SNP) | VAF 247/999 reads (25%) | called by muse, mutect2, varscan2
- GRIN2C | c.769C>T p.L257= | Silent (SNP) | VAF 105/306 reads (34%) | called by muse, mutect2, varscan2
- GUCA1C | c.483A>G p.K161= | Silent (SNP) | VAF 87/312 reads (28%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1764G>A p.S588= | Silent (SNP) | VAF 88/345 reads (26%) | catalogued as rs745388879, COSV56263381; called by muse, mutect2, varscan2
- KCNC1 | c.1425C>T p.V475= | Silent (SNP) | VAF 138/497 reads (28%) | catalogued as rs755628813, COSV56395720; called by muse, mutect2, varscan2
- KCNN3 | c.90G>A p.Q30= | Silent (SNP) | VAF 135/738 reads (18%) | catalogued as rs1360893418; called by muse, mutect2, varscan2
- LRRTM4 | c.144G>A p.E48= | Silent (SNP) | VAF 129/567 reads (23%) | catalogued as rs1371045223; called by muse, mutect2, varscan2
- NMB | c.6C>G p.A2= | Silent (SNP) | VAF 307/906 reads (34%) | called by muse, mutect2, varscan2
- OR6Y1 | c.669C>T p.Y223= | Silent (SNP) | VAF 165/696 reads (24%) | catalogued as rs537972026, COSV56928838; called by muse, mutect2, varscan2
- SDK2 | c.4140C>A p.R1380= | Silent (SNP) | VAF 195/473 reads (41%) | catalogued as rs1163126033; called by muse, mutect2, varscan2
- SEMA3F | c.2103C>T p.A701= | Silent (SNP) | VAF 179/566 reads (32%) | catalogued as rs775821212; called by muse, mutect2, varscan2
- STXBP6 | c.246C>T p.L82= | Silent (SNP) | VAF 95/419 reads (23%) | catalogued as rs374634547; called by muse, mutect2, varscan2
- TSC22D2 | c.1683A>G p.L561= | Silent (SNP) | VAF 176/906 reads (19%) | catalogued as rs753814825; called by muse, mutect2, varscan2
- TSGA10IP | c.15C>G p.T5= | Silent (SNP) | VAF 101/382 reads (26%) | catalogued as COSV101598412; called by muse, mutect2, varscan2
- TTBK1 | c.237C>T p.A79= | Silent (SNP) | VAF 125/540 reads (23%) | catalogued as rs774455336; called by muse, mutect2, varscan2
- UNC45B | c.774G>A p.R258= | Silent (SNP) | VAF 58/386 reads (15%) | called by muse, mutect2, varscan2
- VN1R4 | c.540T>G p.R180= | Silent (SNP) | VAF 112/363 reads (31%) | called by muse, mutect2, varscan2
- ALDH2 | c.115-6244G>A | Intron (SNP) | VAF 16/480 reads (3%) | catalogued as rs1383455944; called by muse, mutect2
- ARHGAP27P2 | n.304A>G | RNA (SNP) | VAF 40/354 reads (11%) | called by muse, mutect2, varscan2
- ECSIT | c.*25C>T | 3'UTR (SNP) | VAF 131/608 reads (22%) | called by muse, mutect2, varscan2
- MCCC2 | c.-28G>T | 5'UTR (SNP) | VAF 73/1044 reads (7%) | called by muse, mutect2
- MPI | c.844+74_844+76del | Intron (DEL) | VAF 63/538 reads (12%) | catalogued as rs1440664472; called by mutect2, pindel, varscan2
- RSAD1 | c.474+74C>T | Intron (SNP) | VAF 50/347 reads (14%) | called by muse, mutect2, varscan2
- UBTFL2 | n.371T>C | RNA (SNP) | VAF 228/1709 reads (13%) | catalogued as rs772588693; called by muse, mutect2, varscan2
